Somatic mutation profile of tumor specimen TCGA-D8-A1J8-01A (aliquot TCGA-D8-A1J8-01A-11D-A13L-09) from TCGA case TCGA-D8-A1J8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.9 years (28,444 days).
Specimen TCGA-D8-A1J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ee90522-0275-44b9-8b18-f887a377dd84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1J8-10A (Blood Derived Normal), aliquot TCGA-D8-A1J8-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0e96cb7-700d-475e-8f06-d3b66fec6e0c

The open-access MAF lists 824 somatic variants for this specimen: 620 protein-altering or splice-affecting, 191 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 506, Silent 191, Frame Shift Del 42, Nonsense Mutation 42, Splice Site 14, Frame Shift Ins 9, Intron 5, In Frame Del 4, 3'UTR 3, Splice Region 2, RNA 2, 5'Flank 2.

Variants (750 of 824; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG | c.477dup p.E160Rfs*10 | Frame Shift Ins (INS) | VAF 79/240 reads (33%) | catalogued as rs746683647; ClinVar: pathogenic; called by mutect2, varscan2
- G6PD | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs137852345, CM973147, COSV63703118; ClinVar: other / pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.1710del p.K570Nfs*7 | Frame Shift Del (DEL) | VAF 51/162 reads (31%) | catalogued as rs1563244807, CD992746; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 70/130 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs121909223, CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50964259; called by muse, mutect2, varscan2
- ABCA4 | c.6654C>G p.I2218M | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV64673402; called by muse, mutect2, varscan2
- ABCA4 | c.2053A>T p.T685S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV64673408; called by muse, mutect2, varscan2
- ABCB9 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54891691; called by muse, mutect2, varscan2
- ABCG4 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV56642768; called by muse, mutect2, varscan2
- ABLIM3 | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.524); catalogued as COSV58643090; called by muse, mutect2, varscan2
- AC242842.3 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as rs1355447485; called by muse, mutect2, varscan2
- ACIN1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs768412898, COSV52975995; called by muse, mutect2, varscan2
- ACOT12 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs769986706, COSV56894777; called by muse, mutect2, varscan2
- ACRV1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 123/212 reads (58%) | catalogued as COSV59754910; called by muse, mutect2, varscan2
- ACTL7A | c.977C>G p.S326C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV61776686; called by muse, mutect2, varscan2
- ACTN2 | c.1683C>G p.F561L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV63974801, COSV63978844; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 38/98 reads (39%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS9 | c.2533A>T p.I845F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99898813; called by muse, mutect2
- ADCK5 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as rs1402650380, COSV58233520; called by muse, mutect2, varscan2
- ADGRG4 | c.6805G>C p.E2269Q | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV54952143, COSV99794496; called by muse, mutect2
- ADGRL4 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs751762953, COSV100875688, COSV66061500; called by muse, mutect2, varscan2
- ADNP2 | c.659G>A p.C220Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV51536401; called by muse, mutect2, varscan2
- ADORA1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58809294; called by muse, mutect2, varscan2
- AFG1L | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs186208029; called by muse, mutect2, varscan2
- AHI1 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV55627461; called by muse, mutect2, varscan2
- AHNAK2 | c.10891G>A p.V3631M | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs777682333, COSV60914884; called by muse, mutect2, varscan2
- AK7 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV50878974; called by muse, mutect2
- AK9 | c.5666G>A p.R1889K | Missense Mutation (SNP) | VAF 96/141 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV69851080, COSV69852955; called by muse, mutect2, varscan2
- AK9 | c.5131A>C p.T1711P | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV69851085; called by muse, mutect2, varscan2
- AKAP9 | c.3478G>C p.E1160Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV62345440; called by muse, mutect2, varscan2
- ALG10 | c.243G>C p.W81C | Missense Mutation (SNP) | VAF 125/398 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56792513; called by muse, mutect2, varscan2
- ANGPT4 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV67921508; called by muse, mutect2, varscan2
- ANK2 | c.2674G>C p.E892Q | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV52160135; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2375G>C p.R792T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51846427, COSV51853752; called by muse, mutect2, varscan2
- AP4E1 | c.1405A>G p.N469D | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.572); catalogued as COSV55916865; called by muse, mutect2
- APBA1 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV55227457; called by muse, mutect2, varscan2
- APBA2 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV67104695; called by muse, mutect2, varscan2
- APOA1 | c.330G>C p.M110I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs745829293, COSV52635702; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 66/156 reads (42%) | catalogued as rs749401724; called by mutect2, varscan2
- ARHGAP12 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV60963102; called by muse, mutect2, varscan2
- ARHGAP6 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.193); catalogued as COSV61627624; called by muse, mutect2, varscan2
- ARMC3 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53061017; called by muse, mutect2, varscan2
- ARMC5 | c.2526C>A p.F842L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV51656307; called by muse, mutect2, varscan2
- ARMCX6 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.618); catalogued as COSV62680738; called by muse, mutect2, varscan2
- ARSK | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV66169640; called by muse, mutect2, varscan2
- ATP13A1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV52285563; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV52873233; called by muse, mutect2, varscan2
- ATP8B1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99376873; called by muse, mutect2
- ATRIP | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as COSV56496945; called by muse, mutect2, varscan2
- AVL9 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV59465538; called by muse, mutect2, varscan2
- B3GALT4 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV101005562; called by muse, mutect2, varscan2
- BBS9 | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as COSV54166982; called by muse, varscan2
- BCAP31 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs782366321, COSV61451626; called by muse, mutect2, varscan2
- BICC1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV54063568; called by muse, mutect2, varscan2
- BIRC6 | c.7951C>T p.Q2651* | Nonsense Mutation (SNP) | VAF 7/125 reads (6%) | catalogued as COSV101427917; called by muse, mutect2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs763134487; called by mutect2, varscan2
- BRF1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777141032, COSV59268700; called by muse, mutect2, varscan2
- BRINP1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56299436; called by muse, mutect2, varscan2
- BRINP3 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV66523416; called by muse, mutect2, varscan2
- BUB1 | c.1277-1G>T p.X426_splice | Splice Site (SNP) | VAF 78/206 reads (38%) | catalogued as COSV57063451; called by muse, mutect2, varscan2
- C12orf66 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs1348369096, COSV61322753; called by muse, mutect2, varscan2
- C20orf194 | c.2129A>G p.Q710R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs781043941, COSV52695624; called by muse, mutect2, varscan2
- C2orf42 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.264); catalogued as COSV52450132; called by muse, mutect2, varscan2
- C7orf61 | c.571dup p.R191Pfs*24 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | catalogued as rs767078637; called by mutect2, pindel, varscan2
- CA8 | c.576+2T>C p.X192_splice | Splice Site (SNP) | VAF 9/96 reads (9%) | catalogued as COSV100526685; called by muse, mutect2
- CA9 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775245763, COSV100253229, COSV61405985; called by muse, mutect2, varscan2
- CACNA1D | c.2663T>C p.F888S (on ENST00000350061 / NM_001128840.3; = p.F908S on NM_000720.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55446304; called by muse, mutect2, varscan2
- CACNA2D2 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1192786729, COSV56563314; called by muse, mutect2, varscan2
- CADPS2 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 45/129 reads (35%) | catalogued as COSV57362406; called by muse, mutect2, varscan2
- CASS4 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV64386375; called by muse, mutect2, varscan2
- CCDC148 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51759784; called by muse, mutect2, varscan2
- CCDC173 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV71653398; called by muse, mutect2, varscan2
- CCDC173 | c.173T>A p.I58N | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV69572883; called by muse, mutect2, varscan2
- CCDC183 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV62012567, COSV62013139; called by muse, mutect2, varscan2
- CCNT1 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as COSV56064198; called by muse, mutect2, varscan2
- CD1B | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs781386448, COSV100939247, COSV63804274; called by muse, mutect2, varscan2
- CD83 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100997724; called by muse, mutect2
- CD96 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as rs1274852667, COSV51916164; called by muse, mutect2, varscan2
- CDK15 | c.914A>G p.N305S (on ENST00000652192 / NM_001366386.2; = p.N254S on NM_139158.2) | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs757384628, COSV53634132; called by muse, mutect2, varscan2
- CDK6 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as rs1286562417, COSV56007691; called by muse, mutect2, varscan2
- CDO1 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51665170; called by muse, mutect2, varscan2
- CDYL2 | c.780C>G p.F260L | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV73653824, COSV73654171; called by muse, mutect2, varscan2
- CEACAM4 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.425); catalogued as COSV55731638; called by muse, mutect2, varscan2
- CEP41 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as COSV56219513; called by muse, mutect2, varscan2
- CFAP47 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 42/71 reads (59%) | catalogued as COSV52884313; called by muse, mutect2, varscan2
- CHD6 | c.8026G>A p.E2676K | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV64690542; called by muse, mutect2, varscan2
- CHD8 | c.7112dup p.N2371Kfs*2 (on ENST00000646647 / NM_001170629.2; = p.N2092Kfs*2 on NM_020920.4) | Frame Shift Ins (INS) | VAF 46/179 reads (26%) | catalogued as rs751094013; called by mutect2, varscan2
- CHD8 | c.4204C>T p.R1402* (on ENST00000646647 / NM_001170629.2; = p.R1123* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 51/215 reads (24%) | catalogued as rs1334692966, COSV63219087; called by muse, mutect2, varscan2
- CHRNA1 | c.547G>C p.D183H (on ENST00000261007 / NM_001039523.3; = p.D158H on NM_000079.4) | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53682826; called by muse, mutect2, varscan2
- CLEC16A | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs776955669, COSV68499412; called by muse, mutect2, varscan2
- CLIC2 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs782061657, COSV58936488; called by muse, mutect2, varscan2
- CLIC6 | c.2036G>A p.R679K (on ENST00000360731 / NM_001317009.2; = p.R661K on NM_053277.3) | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV62447644; called by muse, mutect2, varscan2
- CLOCK | c.2455C>T p.Q819* | Nonsense Mutation (SNP) | VAF 16/246 reads (7%) | catalogued as COSV100011618; called by muse, mutect2
- CLPTM1L | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV57990420; called by muse, mutect2, varscan2
- CLUAP1 | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV100489522; called by muse, mutect2, varscan2
- CMYA5 | c.5356A>T p.I1786F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV101484397, COSV71405789; called by muse, mutect2, varscan2
- CNGA4 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs759955658, COSV56411269; called by muse, mutect2, varscan2
- CNOT1 | c.5563C>G p.L1855V | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV55316384; called by muse, mutect2, varscan2
- CNOT1 | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55316400; called by muse, mutect2, varscan2
- CNOT4 | c.856G>T p.G286W (on ENST00000315544 / NM_001190848.1; = p.G283W on NM_013316.4) | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.431); catalogued as COSV59652321; called by muse, mutect2, varscan2
- COBL | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV54345010; called by muse, mutect2, varscan2
- COL4A4 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631969; called by muse, mutect2, varscan2
- COL5A2 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.43); catalogued as COSV66409095, COSV66409577; called by muse, mutect2, varscan2
- COQ6 | c.385A>T p.I129L | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV53178721; called by muse, mutect2, varscan2
- CORIN | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.253); catalogued as COSV56691226; called by muse, mutect2, varscan2
- CPA1 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50569553; called by muse, mutect2, varscan2
- CPT1C | c.1935G>A p.M645I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1427935613, COSV54919080; called by muse, mutect2, varscan2
- CRB1 | c.3577G>A p.D1193N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV66330212; called by muse, mutect2, varscan2
- CRHBP | c.544+1G>A p.X182_splice | Splice Site (SNP) | VAF 23/81 reads (28%) | catalogued as rs1226118355, COSV57188485; called by muse, mutect2, varscan2
- CRNKL1 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV66105834; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CSE1L | c.1711T>G p.Y571D | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53701789; called by muse, mutect2, varscan2
- CSPP1 | c.3148C>T p.Q1050* (on ENST00000676605; = p.Q1009* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV51584180; called by muse, mutect2, varscan2
- CTRC | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65621454; called by muse, mutect2, varscan2
- CTSS | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV64566305; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV54744348; called by muse, mutect2, varscan2
- CWF19L2 | c.2159G>C p.R720T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV56512179; called by muse, mutect2, varscan2
- CYP4X1 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV64150625; called by muse, mutect2, varscan2
- DAAM1 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62836152; called by muse, mutect2, varscan2
- DAAM1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV62836158; called by muse, mutect2, varscan2
- DAB2 | c.544-1G>A p.X182_splice | Splice Site (SNP) | VAF 42/115 reads (37%) | catalogued as COSV100297807; called by muse, mutect2, varscan2
- DCDC1 | c.3586G>C p.E1196Q (on ENST00000597505 / NM_001367979.1; = p.E303Q on NM_020869.3) | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV60306229; called by muse, mutect2, varscan2
- DCHS1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.321); catalogued as rs775346697, COSV100202303, COSV55034407; called by muse, mutect2, varscan2
- DCN | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99271851; called by muse, mutect2, varscan2
- DCST2 | c.1239C>G p.I413M | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV55051675; called by muse, mutect2, varscan2
- DDX31 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1056415905, COSV60135777; called by muse, mutect2, varscan2
- DDX60 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs1308760097, COSV67095816; called by muse, mutect2, varscan2
- DDX60 | c.1613T>C p.F538S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV101190276; called by muse, mutect2, varscan2
- DDX60 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67096671; called by muse, mutect2, varscan2
- DENND2A | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99325616; called by muse, mutect2
- DENND4B | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs917829296, COSV63409069; called by muse, mutect2, varscan2
- DGKD | c.2055T>A p.C685* (on ENST00000264057 / NM_152879.3; = p.C641* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV51045439; called by muse, mutect2, varscan2
- DGUOK | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV51203571; called by muse, mutect2, varscan2
- DHX29 | c.1834G>C p.D612H | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV52418253; called by muse, mutect2, varscan2
- DHX57 | c.1919G>A p.R640K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54885103; called by muse, mutect2, varscan2
- DHX57 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs571716433, COSV54885117; called by muse, mutect2, varscan2
- DHX57 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.355); catalogued as COSV54885137; called by muse, mutect2, varscan2
- DMAP1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.333); catalogued as COSV60000613; called by muse, mutect2, varscan2
- DMXL1 | c.1967C>T p.S656L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100223393; called by muse, mutect2, varscan2
- DNAH11 | c.10207C>G p.Q3403E | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60954839; called by muse, mutect2, varscan2
- DNAH7 | c.11335C>T p.Q3779* | Nonsense Mutation (SNP) | VAF 74/246 reads (30%) | catalogued as COSV56763886; called by muse, mutect2, varscan2
- DNAJB14 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1329911792, COSV56454949; called by muse, mutect2
- DOCK10 | c.4759C>G p.L1587V | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99287875; called by muse, mutect2
- DOCK9 | c.3826G>T p.D1276Y (on ENST00000376460 / NM_001366676.2; = p.D1277Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV59628477; called by muse, mutect2, varscan2
- DPY19L2 | c.2003C>G p.A668G | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV61041763; called by muse, mutect2, varscan2
- DQX1 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57817115; called by muse, mutect2, varscan2
- DTX4 | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.82); catalogued as rs1175028009, COSV57090494; called by muse, mutect2, varscan2
- DYNC1H1 | c.10745G>A p.R3582Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs866994746, COSV64136758; called by muse, mutect2, varscan2
- DYNC2H1 | c.1958C>G p.S653* | Nonsense Mutation (SNP) | VAF 26/45 reads (58%) | catalogued as rs1029379106, COSV62093651; called by muse, mutect2, varscan2
- DYNC2I1 | c.1981C>A p.H661N | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV68104687; called by muse, mutect2, varscan2
- EIF5B | c.3313C>G p.R1105G | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51484830, COSV51490083; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs751148694; called by mutect2, varscan2
- EML4 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 65/190 reads (34%) | catalogued as COSV59297535; called by muse, mutect2, varscan2
- ENAH | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 115/480 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs770948804, COSV52867752; called by muse, varscan2
- EP400 | c.3036T>A p.N1012K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57771603; called by muse, mutect2, varscan2
- EPB41L2 | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 83/121 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs778911472, COSV100440573, COSV61355168; called by muse, mutect2, varscan2
- EPHA5 | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.464); catalogued as rs769104997, COSV56666540, COSV99897250; called by muse, mutect2, varscan2
- ERBIN | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV52311769, COSV52315902, COSV99396707; called by muse, mutect2, varscan2
- ERBIN | c.2631G>C p.E877D | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.011); catalogued as COSV52315934; called by muse, mutect2, varscan2
- ERBIN | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.339); catalogued as COSV52315964; called by muse, mutect2, varscan2
- ERBIN | c.3268G>T p.D1090Y | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52316002; called by muse, mutect2, varscan2
- ERBIN | c.3946G>A p.E1316K (on ENST00000284037 / NM_001253697.2; = p.E1275K on NM_018695.4) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.664); catalogued as COSV52316034; called by muse, mutect2, varscan2
- ESR2 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50830731; called by muse, mutect2, varscan2
- F2RL2 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.357); catalogued as rs1013566397, COSV56970654; called by muse, mutect2, varscan2
- FAM111A | c.697T>C p.S233P | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1415488206, COSV64655328; called by muse, mutect2, varscan2
- FAM13C | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as rs752207558, COSV53248023; called by muse, mutect2, varscan2
- FAM169A | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770317810, COSV65846048, COSV65846478; called by muse, mutect2, varscan2
- FAM177B | c.209G>C p.W70S | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV62601096; called by muse, mutect2, varscan2
- FAM217B | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV62564277; called by muse, mutect2, varscan2
- FAM47A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60495954; called by muse, mutect2, varscan2
- FAN1 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV58728150; called by muse, mutect2, varscan2
- FBF1 | c.1565C>T p.S522L (on ENST00000586717; = p.S536L on NM_001319193.1) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs540051078, COSV59864986; called by muse, mutect2, varscan2
- FBN3 | c.4393G>A p.G1465S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746124719, COSV54459982; called by muse, mutect2, varscan2
- FBXL5 | c.1946C>G p.S649* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV58010848, COSV58013862; called by muse, mutect2, varscan2
- FBXO24 | c.946G>A p.V316I (on ENST00000241071 / NM_033506.3; = p.V354I on NM_012172.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140728414; called by muse, mutect2, varscan2
- FCRL5 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.304); catalogued as rs1278643998, COSV62514305; called by muse, mutect2, varscan2
- FGF18 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV99208596; called by mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 46/145 reads (32%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FKBP8 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV55892255; called by muse, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD1 | c.2908C>G p.H970D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV66700306; called by muse, mutect2, varscan2
- FTO | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV67111565; called by muse, mutect2, varscan2
- FZD10 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767950238, COSV57473530; called by muse, mutect2, varscan2
- FZD5 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs753318203, COSV54943512; called by muse, mutect2, varscan2
- G3BP2 | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62976314; called by muse, mutect2, varscan2
- GABRA3 | c.1215C>G p.I405M | Missense Mutation (SNP) | VAF 104/185 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV64798382; called by muse, mutect2, varscan2
- GABRR3 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); catalogued as COSV72084096; called by muse, mutect2, varscan2
- GALK2 | c.389T>A p.M130K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV59101254; called by muse, mutect2, varscan2
- GALNT13 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV101223796, COSV67220220; called by muse, varscan2
- GALNT5 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV52037695; called by muse, mutect2, varscan2
- GAREM1 | c.2181del p.R728Gfs*5 (on ENST00000269209 / NM_001242409.2; = p.R727Gfs*5 on NM_022751.3) | Frame Shift Del (DEL) | VAF 23/48 reads (48%) | catalogued as rs1372790960; called by mutect2, pindel, varscan2
- GARNL3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1398652956, COSV59226138; called by muse, mutect2, varscan2
- GATA3 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV60515516, COSV60515743; called by muse, mutect2, varscan2
- GIGYF1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs780767946, COSV99308872; called by muse, mutect2
- GIGYF2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV101003828, COSV65249132; called by muse, mutect2, varscan2
- GINS1 | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV52465269; called by muse, mutect2, varscan2
- GLDC | c.256-1G>A p.X86_splice | Splice Site (SNP) | VAF 23/63 reads (37%) | catalogued as COSV58679781; called by muse, mutect2, varscan2
- GLP1R | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV100952466; called by muse, mutect2
- GM2A | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV64095509; called by muse, mutect2, varscan2
- GNPDA2 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.005); catalogued as COSV54946661; called by muse, mutect2, varscan2
- GOLGB1 | c.8386G>A p.E2796K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as COSV100510379; called by muse, mutect2, varscan2
- GP6 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.117); catalogued as rs369642453; called by muse, mutect2, varscan2
- GPR12 | c.454A>T p.R152W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67344325; called by muse, mutect2, varscan2
- GPR75 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as rs776855671, COSV61827069; called by muse, varscan2
- GRIK1 | c.2113A>G p.T705A | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58717612; called by muse, mutect2, varscan2
- GTF3C5 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs140794229; called by muse, mutect2, varscan2
- H3-5 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV61187197; called by muse, mutect2, varscan2
- H3C2 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV52518668; called by muse, mutect2, varscan2
- HDAC4 | c.981G>A p.T327= | Splice Region (SNP) | VAF 16/43 reads (37%) | catalogued as rs895364750, COSV61864965; called by muse, mutect2, varscan2
- HEPH | c.1463T>C p.F488S (on ENST00000343002; = p.F221S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.101); catalogued as COSV57963540; called by muse, mutect2, varscan2
- HERC2 | c.12721C>T p.R4241W | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55322728; called by muse, mutect2, varscan2
- HHIPL1 | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs986697468, COSV58090397; called by muse, mutect2, varscan2
- HIF1A | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs776377120, COSV60189195; called by muse, mutect2, varscan2
- HIPK3 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs1462514078, COSV57562421; called by muse, mutect2, varscan2
- HIVEP1 | c.6514C>T p.R2172* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs750361782, COSV65101189; called by muse, mutect2, varscan2
- HMCN1 | c.16270G>A p.E5424K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV54897481, COSV54907870, COSV54934854; called by muse, mutect2, varscan2
- HMGB4 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53910179; called by muse, mutect2, varscan2
- HNF4G | c.112C>T p.R38C (on ENST00000354370 / NM_001330561.2; = p.R85C on NM_004133.5) | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772036366, COSV62965321; called by muse, mutect2, varscan2
- HNRNPC | c.571G>A p.D191N (on ENST00000420743; = p.D178N on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.94); catalogued as COSV60144380, COSV60144967; called by muse, mutect2, varscan2
- HOOK2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53402269; called by muse, mutect2, varscan2
- HRH4 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV56928021; called by muse, mutect2, varscan2
- HS6ST1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs879255383, COSV52128151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSDL2 | c.1250G>C p.R417T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV52714846; called by muse, mutect2, varscan2
- HTT | c.5717T>C p.V1906A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61861709; called by muse, mutect2, varscan2
- HYDIN | c.3665A>C p.K1222T | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as COSV66832012; called by muse, mutect2, varscan2
- IFFO1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60737487; called by muse, mutect2, varscan2
- IL1RAPL2 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV61156213, COSV61158511; called by muse, mutect2, varscan2
- IL34 | c.39C>G p.I13M | Missense Mutation (SNP) | VAF 117/192 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV55380121; called by muse, mutect2, varscan2
- INF2 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1416500072, COSV53032400; called by muse, mutect2, varscan2
- ING3 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as rs908317865, COSV59950940; called by muse, mutect2, varscan2
- INTS9 | c.1346A>G p.D449G | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV68434071; called by muse, mutect2, varscan2
- IQCH | c.2489G>A p.S830N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV60049832; called by muse, mutect2
- ITIH3 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as COSV69648729; called by muse, mutect2, varscan2
- ITK | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as rs1393642606, COSV70062228; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1600G>A p.E534K (on ENST00000439118 / NM_001008949.3; = p.E542K on NM_178495.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.056); catalogued as rs1332124306, COSV63153280; called by muse, mutect2, varscan2
- IZUMO1 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV59568264; called by muse, mutect2, varscan2
- JADE2 | c.2035G>C p.E679Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV99252816; called by muse, mutect2, varscan2
- JAG1 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.423); catalogued as COSV54756499; called by muse, mutect2, varscan2
- JAM2 | c.633A>T p.E211D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100467859; called by muse, mutect2
- JMJD1C | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV67861385; called by muse, mutect2, varscan2
- JMY | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as rs1294915263, COSV68660869; called by muse, mutect2, varscan2
- JPH4 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58112404; called by muse, mutect2, varscan2
- KAT14 | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV66607638; called by muse, mutect2, varscan2
- KATNIP | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs181329078, COSV55180034; called by mutect2, varscan2
- KBTBD2 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.354); catalogued as COSV58363407; called by muse, mutect2, varscan2
- KCNA6 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54975107; called by muse, mutect2, varscan2
- KCNA6 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.959); catalogued as COSV54973930; called by muse, mutect2, varscan2
- KCNT2 | c.1709G>C p.R570T | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV54078486; called by muse, mutect2, varscan2
- KDM5C | c.3319G>C p.D1107H | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV64764393, COSV64764813; called by muse, mutect2, varscan2
- KDR | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55761307, COSV55764576; called by muse, mutect2, varscan2
- KEL | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.675); catalogued as COSV62337243; called by muse, mutect2
- KIAA0930 | c.896G>A p.R299Q (on ENST00000336156 / NM_001009880.2; = p.R304Q on NM_015264.2) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); catalogued as rs368253058; called by muse, mutect2, varscan2
- KIAA1755 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs776676300, COSV54076287; called by muse, mutect2, varscan2
- KIF11 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs767891884, COSV53270533; called by muse, mutect2, varscan2
- KIF14 | c.4231-1G>A p.X1411_splice | Splice Site (SNP) | VAF 16/176 reads (9%) | catalogued as COSV100950644; called by muse, mutect2
- KIFAP3 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV100846749; called by muse, mutect2
- KIR3DL3 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs1306523442; called by muse, mutect2, varscan2
- KPNB1 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 93/160 reads (58%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV51596894; called by muse, mutect2, varscan2
- KRBA1 | c.2056C>G p.P686A | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55441389; called by muse, mutect2, varscan2
- KRT18 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as COSV66316180; called by muse, mutect2, varscan2
- KRT2 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs1324778278, COSV59010330; called by muse, mutect2, varscan2
- KRT6A | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs1249992103, COSV58105083; called by muse, mutect2, varscan2
- KRTAP13-3 | c.423T>A p.S141R | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV61879171; called by muse, mutect2, varscan2
- LARGE1 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383236787; called by muse, mutect2
- LENG1 | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55362945; called by muse, mutect2, varscan2
- LGI2 | c.1108T>C p.W370R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66122954; called by mutect2, varscan2
- LILRB1 | c.1234C>T p.Q412* (on ENST00000427581; = p.Q376* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 40/122 reads (33%) | catalogued as COSV100206965; called by muse, varscan2
- LRCH2 | c.1114C>G p.H372D | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.452); catalogued as COSV57750176; called by muse, mutect2, varscan2
- LRP1 | c.10195T>C p.C3399R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54510597; called by muse, mutect2, varscan2
- LRP1B | c.11140C>T p.L3714F | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.047); catalogued as rs1336711239, COSV67185170, COSV67189807; called by muse, mutect2, varscan2
- LRRC31 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246352; called by muse, mutect2, varscan2
- LRRTM4 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV69140004; called by muse, mutect2, varscan2
- LTK | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53027537; called by muse, mutect2, varscan2
- LUZP4 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.168); catalogued as rs142869093, COSV64219512; called by muse, mutect2, varscan2
- MAEL | c.656A>T p.D219V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV63112440; called by muse, mutect2, varscan2
- MAGI1 | c.3460G>A p.E1154K (on ENST00000402939 / NM_001033057.2; = p.E1183K on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV58325464; called by muse, mutect2, varscan2
- MAN1A1 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.57); PolyPhen probably damaging (1); catalogued as COSV63787465; called by muse, mutect2, varscan2
- MAP1S | c.2948A>G p.Q983R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV60722606; called by muse, mutect2, varscan2
- MAP3K2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV100777240, COSV61294141; called by muse, mutect2, varscan2
- MAP7 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV63419399; called by muse, mutect2, varscan2
- MAPK15 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.64); PolyPhen benign (0.14); catalogued as COSV62028243; called by muse, mutect2, varscan2
- MBOAT7 | c.1187A>G p.D396G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV55475712; called by muse, mutect2, varscan2
- MDGA1 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1270272647, COSV51792936, COSV51794250; called by muse, mutect2, varscan2
- ME2 | c.1722A>T p.E574D | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV58423148, COSV58424273; called by muse, mutect2, varscan2
- MED13 | c.5590C>T p.R1864C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756749053, COSV67263412; called by muse, mutect2, varscan2
- MED13 | c.3824C>T p.S1275L | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1399568357, COSV67263416; called by muse, varscan2
- MEF2C | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV60930511; called by muse, mutect2, varscan2
- MEP1A | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100042400; called by muse, mutect2
- MLH3 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV53154845; called by muse, mutect2, varscan2
- MMEL1 | c.1926G>C p.Q642H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV56521339; called by muse, mutect2, varscan2
- MOCOS | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54343168; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | catalogued as rs755830405; called by mutect2, varscan2
- MOCS1 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs745903344, COSV51316416; called by muse, mutect2, varscan2
- MORN3 | c.594G>C p.M198I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV62507290; called by muse, mutect2, varscan2
- MPDZ | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 55/131 reads (42%) | catalogued as COSV59917728; called by muse, mutect2, varscan2
- MRE11 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 112/203 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs761458720, COSV60576711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRTFB | c.2362T>C p.F788L (on ENST00000571589 / NM_001365412.2; = p.F738L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.087); catalogued as rs1194536066, COSV100370882; called by muse, mutect2
- MSH6 | c.2462T>C p.L821P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99315170; called by muse, mutect2, varscan2
- MTOR | c.4550C>T p.A1517V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV63871153; called by muse, mutect2, varscan2
- MUC17 | c.6545C>G p.S2182* | Nonsense Mutation (SNP) | VAF 83/244 reads (34%) | catalogued as COSV60287918; called by muse, mutect2, varscan2
- MYH11 | c.5003G>A p.R1668K | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.803); catalogued as rs890481446, COSV55552485; called by muse, mutect2, varscan2
- MYL6B | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as COSV52878730; called by muse, mutect2, varscan2
- MYO7B | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV67347458; called by muse, mutect2, varscan2
- MYOM1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.243); catalogued as COSV55291403; called by muse, mutect2, varscan2
- MYOM2 | c.689T>G p.V230G | Missense Mutation (SNP) | VAF 58/95 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV50711400; called by muse, mutect2, varscan2
- NABP2 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 110/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57212433; called by muse, mutect2, varscan2
- NAV2 | c.1889G>A p.G630D (on ENST00000396087 / NM_001244963.2; = p.G607D on NM_145117.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as COSV62322255; called by muse, mutect2, varscan2
- NBAS | c.3361-1G>C p.X1121_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99867578, COSV99869236; called by muse, varscan2
- NCAM1 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57516118; called by muse, mutect2, varscan2
- NCAPD3 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 70/125 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV73244866; called by muse, mutect2, varscan2
- NCBP1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV100912545; called by muse, mutect2
- NCKAP5 | c.3511G>T p.E1171* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as COSV58442343; called by muse, mutect2, varscan2
- NCL | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV59545793; called by muse, mutect2, varscan2
- NCOA3 | c.3934C>A p.Q1312K (on ENST00000371998 / NM_181659.3; = p.Q1308K on NM_006534.4) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100507206; called by muse, mutect2, varscan2
- NECAP1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60249311; called by muse, mutect2, varscan2
- NES | c.4282G>T p.E1428* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV63960988, COSV63961109; called by muse, mutect2, varscan2
- NFAT5 | c.1460C>G p.S487C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV63027298; called by muse, mutect2, varscan2
- NIBAN1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100836281; called by muse, mutect2
- NID1 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV51619777; called by muse, mutect2, varscan2
- NISCH | c.1240C>G p.L414V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.778); catalogued as rs1239467798, COSV61899744; called by muse, varscan2
- NIT2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV67630374; called by muse, mutect2, varscan2
- NLRC3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57090586; called by muse, mutect2, varscan2
- NLRP1 | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52565115; called by muse, mutect2, varscan2
- NOC4L | c.907del p.X303_splice | Splice Site (DEL) | VAF 12/39 reads (31%) | catalogued as rs765400964; called by mutect2, pindel, varscan2
- NOMO2 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV57916643; called by muse, mutect2, varscan2
- NOP2 | c.895G>A p.E299K (on ENST00000322166 / NM_001258308.2; = p.E295K on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1301911932, COSV59110448; called by muse, mutect2, varscan2
- NOTCH2 | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV56690876; called by muse, mutect2, varscan2
- NPC1L1 | c.2620G>C p.E874Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV56924838; called by muse, mutect2, varscan2
- NPR1 | c.2746G>C p.D916H | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV64117583; called by muse, mutect2, varscan2
- NPRL2 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs149128231, CM160819; called by muse, mutect2, varscan2
- NPVF | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV56060422, COSV56060591; called by muse, varscan2
- NSMAF | c.2447-1G>C p.X816_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | catalogued as COSV50686791; called by muse, mutect2, varscan2
- NTRK1 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs762542314, COSV62324407, COSV62325705, COSV62328205; called by muse, mutect2
- NUP205 | c.1425C>G p.I475M | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as COSV53658813; called by muse, mutect2, varscan2
- NUP43 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs751766292, COSV61189786; called by muse, mutect2, varscan2
- NUTM2F | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 40/121 reads (33%) | catalogued as COSV53557083; called by muse, mutect2, varscan2
- OBSCN | c.12505G>A p.E4169K | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV52772064; called by muse, varscan2
- OBSL1 | c.2800G>C p.D934H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54705793; called by muse, mutect2, varscan2
- OBSL1 | c.2638G>A p.V880I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as rs781481635, COSV54705808; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSL1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767009179, COSV54718742; called by muse, mutect2, varscan2
- ONECUT2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV72203266; called by muse, mutect2, varscan2
- OR4D10 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV73260024; called by muse, mutect2, varscan2
- OR5H6 | c.745G>T p.G249W (on ENST00000642105; = p.G233W on NM_001005479.2) | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67351420; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 28/53 reads (53%) | catalogued as rs763394045; called by mutect2, varscan2
- PACS1 | c.2538G>C p.K846N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57697571, COSV57700045; called by muse, mutect2, varscan2
- PAPPA | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV60281960; called by muse, mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 93/359 reads (26%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel, varscan2
- PARP15 | c.1970C>T p.P657L (on ENST00000464300 / NM_001113523.3; = p.P423L on NM_152615.2) | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59972561; called by muse, mutect2, varscan2
- PARP4 | c.2355G>C p.L785F | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67961682; called by muse, mutect2, varscan2
- PATJ | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57161640; called by muse, mutect2, varscan2
- PCDH7 | c.2056del p.S686Lfs*47 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as COSV100688790; called by mutect2, pindel, varscan2
- PCDHA12 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV56497369; called by muse, mutect2
- PCDHAC1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.017); catalogued as rs1554204208, COSV53848282; called by muse, mutect2, varscan2
- PDIA2 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763790305, COSV51987043; called by muse, mutect2, varscan2
- PER2 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs748039327, COSV54523531; called by muse, mutect2, varscan2
- PGAP4 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.431); catalogued as rs1389782325, COSV66387630; called by muse, mutect2, varscan2
- PHACTR1 | c.1681A>G p.K561E | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV60666104; called by muse, mutect2, varscan2
- PHF23 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.27); catalogued as COSV99138342; called by muse, mutect2, varscan2
- PIK3CB | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as rs768628634, COSV56685924; called by muse, mutect2, varscan2
- PLB1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV59824662; called by muse, mutect2, varscan2
- PLCB4 | c.1385del p.N462Tfs*4 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | catalogued as rs1489417610; called by mutect2, pindel, varscan2
- PLEKHG2 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs774674904, COSV52682594; called by muse, mutect2, varscan2
- PLPBP | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV60239651; called by muse, mutect2, varscan2
- PLVAP | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1341221728, COSV53084974; called by muse, mutect2, varscan2
- PLXNB1 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866132965, COSV56488853; called by muse, mutect2
- PLXNC1 | c.2174C>G p.S725* | Nonsense Mutation (SNP) | VAF 70/196 reads (36%) | catalogued as COSV51574967; called by muse, varscan2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 61/203 reads (30%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- PNKP | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV55587728; called by muse, mutect2, varscan2
- PNMA3 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs782280451, COSV64722295; called by muse, mutect2, varscan2
- POGLUT2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65683032; called by muse, mutect2, varscan2
- PON1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as rs753947057, COSV55931764; called by muse, mutect2, varscan2
- PRICKLE1 | c.1828G>T p.E610* | Nonsense Mutation (SNP) | VAF 39/108 reads (36%) | catalogued as COSV58206679; called by muse, mutect2, varscan2
- PRKCD | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.407); catalogued as rs781980599, COSV57848431; called by muse, mutect2, varscan2
- PRKD2 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52186631, COSV99354692; called by muse, mutect2, varscan2
- PRLR | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV51495380; called by muse, mutect2, varscan2
- PRPF39 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768524269, COSV63276804; called by muse, mutect2, varscan2
- PRPF8 | c.6517G>A p.E2173K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV56773345; called by muse, mutect2, varscan2
- PRX | c.3359G>A p.G1120E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.74); catalogued as rs1240103185, COSV52520841, COSV99396270; called by muse, mutect2, varscan2
- PSD2 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51199700, COSV51201613; called by muse, mutect2, varscan2
- PSG2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV68884563; called by muse, mutect2, varscan2
- PSMD1 | c.2755G>C p.E919Q | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as COSV58078596, COSV58080191; called by muse, mutect2, varscan2
- PSMD12 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV62065689; called by muse, mutect2, varscan2
- PSME4 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV66364825; called by muse, mutect2, varscan2
- PTCD1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV52857527; called by muse, mutect2, varscan2
- PTGS2 | c.1406-2A>G p.X469_splice | Splice Site (SNP) | VAF 24/90 reads (27%) | catalogued as COSV66569251; called by muse, mutect2, varscan2
- PTGS2 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV66569265; called by muse, mutect2, varscan2
- PTPN3 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV52705641; called by muse, mutect2, varscan2
- PTPRB | c.4375G>A p.E1459K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV99716086; called by muse, mutect2
- PTPRT | c.407G>T p.W136L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61980064; called by muse, varscan2
- PUM3 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as COSV65896710; called by muse, mutect2, varscan2
- PYGB | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769655708, COSV53817272; called by muse, mutect2, varscan2
- PYGM | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51216715; called by muse, mutect2, varscan2
- RAD50 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV54751181, COSV54756907; called by muse, mutect2, varscan2
- RAD54L2 | c.2779G>C p.E927Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as rs745850917, COSV99620800; called by mutect2, varscan2
- RALGAPA2 | c.2748del p.S919Afs*24 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as COSV52495885; called by mutect2, pindel, varscan2
- RALGAPA2 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | catalogued as COSV52496782; called by muse, varscan2
- RAP1B | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51668406; called by muse, mutect2, varscan2
- RAPGEF6 | c.4711C>T p.Q1571* | Nonsense Mutation (SNP) | VAF 40/92 reads (43%) | catalogued as COSV57245822; called by muse, mutect2, varscan2
- RASEF | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 13/293 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV100906793; called by muse, mutect2
- RBM28 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 144/444 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV56163022; called by muse, mutect2, varscan2
- RECQL | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 9/235 reads (4%) | catalogued as COSV99556304; called by muse, mutect2
- REEP4 | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs192178384; called by muse, mutect2, varscan2
- REN | c.833C>A p.S278* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV65817741; called by muse, mutect2, varscan2
- RET | c.2536C>A p.L846I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV60693841; called by muse, mutect2, varscan2
- RIMBP2 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV99898516; called by muse, mutect2, varscan2
- RNF103 | c.1330A>G p.N444D | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778172142, COSV52894781; called by muse, mutect2, varscan2
- RPL13A | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52619126; called by muse, mutect2, varscan2
- RPTOR | c.3430G>A p.V1144M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs766868607, COSV60804150, COSV60808263; called by muse, mutect2, varscan2
- RUBCN | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56365874; called by muse, mutect2, varscan2
- RUFY1 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60160237; called by muse, mutect2, varscan2
- RUNDC1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV64511814; called by muse, mutect2, varscan2
- RXFP4 | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100562753; called by muse, mutect2, varscan2
- RYR2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs555183066, COSV63684249; called by muse, mutect2, varscan2
- SACS | c.8132C>T p.S2711L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1213203489, COSV66539562; called by muse, mutect2, varscan2
- SAMD3 | c.186del p.K62Nfs*9 | Frame Shift Del (DEL) | VAF 17/127 reads (13%) | catalogued as rs770241311; called by mutect2, pindel, varscan2
- SCAF8 | c.2072-1G>T p.X691_splice | Splice Site (SNP) | VAF 67/96 reads (70%) | catalogued as COSV63200210; called by muse, mutect2, varscan2
- SEC14L3 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV53179128; called by muse, mutect2, varscan2
- SEMA3C | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54846064; called by muse, mutect2, varscan2
- SEMA4F | c.1778G>C p.W593S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV60283219; called by muse, mutect2, varscan2
- SEMA6D | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1462447868, COSV60375236, COSV60377127; called by muse, mutect2, varscan2
- SERPINA11 | c.1163C>G p.S388* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV58241794; called by muse, mutect2, varscan2
- SERPINB3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as rs143123968, COSV52190153; called by muse, mutect2, varscan2
- SERPINB4 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV61984877; called by muse, mutect2, varscan2
- SERTM1 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1234968063, COSV59376413; called by muse, mutect2, varscan2
- SETBP1 | c.3280C>G p.Q1094E | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56321434, COSV56328158; called by muse, mutect2, varscan2
- SFSWAP | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55521840, COSV99906117; called by muse, mutect2, varscan2
- SGSM1 | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.574); catalogued as rs779714195, COSV68510284; called by muse, mutect2, varscan2
- SHC2 | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99198924; called by muse, varscan2
- SIPA1L2 | c.1484-1G>C p.X495_splice | Splice Site (SNP) | VAF 59/186 reads (32%) | catalogued as COSV99477303; called by muse, mutect2, varscan2
- SLC22A16 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as rs368955884; called by muse, mutect2, varscan2
- SLC26A8 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 186/270 reads (69%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.454); catalogued as rs767361951, COSV62884703; called by muse, mutect2, varscan2
- SLC26A9 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.863); catalogued as COSV61600710; called by muse, mutect2, varscan2
- SLC46A1 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.792); catalogued as COSV50229388; called by muse, varscan2
- SLC6A11 | c.1235T>C p.F412S | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54393313; called by muse, mutect2, varscan2
- SLC6A4 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99911230; called by muse, mutect2, varscan2
- SLC9C2 | c.2227T>C p.Y743H | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62945684; called by muse, mutect2, varscan2
- SLIT2 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56571141; called by muse, mutect2, varscan2
- SLX4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV53563828; called by muse, mutect2, varscan2
- SMARCD3 | c.946G>T p.D316Y (on ENST00000262188 / NM_001003801.2; = p.D303Y on NM_003078.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs758051223, COSV99222802; called by muse, mutect2, varscan2
- SMG7 | c.3013C>T p.H1005Y | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV61631141; called by muse, mutect2, varscan2
- SMOC2 | c.615G>T p.Q205H (on ENST00000356284 / NM_001166412.2; = p.Q216H on NM_022138.3) | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV62434292, COSV62437486; called by muse, varscan2
- SNED1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV60023982; called by muse, mutect2, varscan2
- SNTG2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs1268834080, COSV100421578; called by muse, mutect2
- SOX30 | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53937343; called by muse, mutect2, varscan2
- SOX30 | c.1830C>G p.F610L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779168856, COSV53937351, COSV99398723; called by muse, mutect2, varscan2
- SPATA31D1 | c.2855C>G p.S952C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs760591635, COSV61193137; called by muse, mutect2, varscan2
- SPATA31E1 | c.4136C>T p.P1379L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs557844478, COSV57791311; called by muse, mutect2, varscan2
- SPATA7 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs1023367360, COSV50416958; called by muse, mutect2, varscan2
- SPEN | c.2854G>A p.V952M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV65361571; called by muse, mutect2, varscan2
- SPTBN4 | c.2594A>G p.E865G | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58949003; called by muse, mutect2, varscan2
- SPTBN5 | c.3986G>A p.W1329* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as rs1019177831, COSV100310806; called by muse, mutect2
- SRC | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1328205125, COSV62439817; called by muse, mutect2, varscan2
- STAT1 | c.1778A>T p.D593V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV63116019; called by muse, mutect2, varscan2
- STRADB | c.1225C>G p.P409A | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52043600; called by muse, mutect2, varscan2
- STX17 | c.451C>G p.Q151E | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99407859; called by muse, mutect2
- STXBP3 | c.273C>G p.F91L | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV64182164; called by muse, mutect2, varscan2
- STXBP4 | c.1363A>G p.R455G | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV100894604; called by muse, mutect2
- SYBU | c.84G>C p.L28F (on ENST00000276646 / NM_001099754.2; = p.L27F on NM_017786.6) | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52617700; called by muse, mutect2, varscan2
- SYNE2 | c.15716G>A p.G5239E | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV59950229; called by muse, mutect2, varscan2
- SYNPO | c.1376C>T p.A459V (on ENST00000394243 / NM_001166208.2; = p.A215V on NM_007286.6) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56940074; called by muse, mutect2, varscan2
- SYS1 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54781747; called by muse, mutect2, varscan2
- SYT17 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV62546141; called by muse, mutect2, varscan2
- TAF1L | c.3565A>T p.T1189S | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV54261621; called by muse, mutect2, varscan2
- TAF4 | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53344713; called by muse, mutect2
- TAS2R1 | c.469A>T p.R157W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1183193912, COSV66778497; called by muse, mutect2, varscan2
- TBC1D8B | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1408223853, COSV52178534; called by muse, mutect2, varscan2
- TBR1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67417789; called by muse, mutect2, varscan2
- TBR1 | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV67417796; called by muse, mutect2, varscan2
- TBRG4 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143689271; called by muse, mutect2, varscan2
- TCERG1 | c.2896G>T p.D966Y | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57036995; called by muse, mutect2, varscan2
- TCHH | c.1840_1842del p.E614del | In Frame Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs774216956; called by pindel, varscan2
- TEC | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs761984494, COSV63353933; called by muse, mutect2, varscan2
- TEDC2 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV53539895; called by muse, mutect2, varscan2
- TENM3 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV69307277; called by muse, mutect2, varscan2
- TESPA1 | c.1465G>A p.E489K (on ENST00000316577 / NM_001098815.3; = p.E351K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV57257085; called by muse, mutect2, varscan2
- TET2 | c.742C>G p.H248D | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99481280; called by muse, mutect2, varscan2
- TEX30 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV65696859; called by muse, mutect2, varscan2
- TGM7 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV71772788; called by muse, mutect2, varscan2
- THADA | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV57683113; called by muse, mutect2, varscan2
- THSD7A | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV70264439; called by muse, mutect2, varscan2
- THSD7B | c.4336G>A p.E1446K (on ENST00000272643; = p.E1444K on NM_001316349.2) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as rs371759413; called by muse, mutect2, varscan2
- THTPA | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as rs1490769188, COSV55338124; called by muse, mutect2, varscan2
- THTPA | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); catalogued as COSV55338133; called by muse, mutect2, varscan2
- TIMELESS | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57511246; called by muse, mutect2, varscan2
- TIMELESS | c.1588_1589del p.K530Efs*18 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs745470465; called by mutect2, pindel
- TJP1 | c.2078C>T p.T693I | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100632372; called by muse, mutect2
- TLN2 | c.626G>A p.R209K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV60889532; called by muse, mutect2, varscan2
- TLR4 | c.2098G>T p.V700L (on ENST00000355622 / NM_138554.5; = p.V660L on NM_003266.4) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs201612590; called by muse, varscan2
- TMED4 | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV56941883; called by muse, varscan2
- TMEM131 | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 18/440 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV99486685; called by muse, mutect2
- TMEM132D | c.2379C>G p.I793M | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV67158798, COSV67160296; called by muse, mutect2, varscan2
- TMEM176B | c.500C>G p.S167* | Nonsense Mutation (SNP) | VAF 53/145 reads (37%) | catalogued as COSV58439601; called by muse, mutect2, varscan2
- TMEM50B | c.123G>C p.M41I | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV70279084; called by muse, varscan2
- TMEM52B | c.488C>A p.P163H (on ENST00000381923 / NM_001079815.1; = p.P143H on NM_153022.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53728185; called by muse, mutect2, varscan2
- TMX3 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs746563370, COSV55185310; called by muse, mutect2, varscan2
- TNNT3 | c.295_297dup p.E99dup (on ENST00000397301 / NM_001367846.1; = p.E88dup on NM_006757.4) | In Frame Ins (INS) | VAF 15/28 reads (54%) | catalogued as rs764019640; called by mutect2, varscan2
- TOX4 | c.1402C>G p.P468A | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52968782; called by muse, mutect2, varscan2
- TP63 | c.1889C>G p.S630C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV53198253, COSV53205358; called by muse, mutect2, varscan2
- TRAF3IP3 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.281); catalogued as COSV50552697; called by muse, mutect2, varscan2
- TRAK2 | c.2517G>C p.K839N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60271916; called by muse, mutect2, varscan2
- TRIM14 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58354200; called by muse, mutect2, varscan2
- TRIM24 | c.3127A>G p.I1043V (on ENST00000343526 / NM_015905.3; = p.I1009V on NM_003852.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs780616900, COSV58972090; called by muse, mutect2, varscan2
- TRIM29 | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100531501; called by muse, mutect2
- TRIM3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs775651527, COSV61983834; called by muse, mutect2, varscan2
- TRMT11 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 69/104 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as COSV57672863; called by muse, mutect2, varscan2
- TRMT9B | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373979768, COSV71600217; called by muse, mutect2, varscan2
- TRPM6 | c.4156C>T p.H1386Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV62509609; called by muse, mutect2, varscan2
- TSEN54 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV51351690; called by muse, mutect2, varscan2
- TTBK2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51160696; called by muse, mutect2, varscan2
- TTC21A | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 48/115 reads (42%) | catalogued as rs767249879, COSV57184914, COSV57186467; called by muse, mutect2, varscan2
- TTLL3 | c.1644G>C p.Q548H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV59614351; called by muse, mutect2, varscan2
- TTN | c.99443A>G p.E33148G (on ENST00000591111; = p.E25724G on NM_003319.4) | Missense Mutation (SNP) | VAF 69/274 reads (25%) | PolyPhen benign (0.177); catalogued as COSV60042890; called by muse, mutect2, varscan2
- TTN | c.77596G>C p.E25866Q (on ENST00000591111; = p.E18442Q on NM_003319.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | PolyPhen benign (0.104); catalogued as COSV100593225, COSV60042925; called by muse, mutect2, varscan2
- TTN | c.73153C>A p.H24385N (on ENST00000591111; = p.H16961N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/166 reads (5%) | PolyPhen possibly damaging (0.584); catalogued as COSV100596622; called by muse, mutect2
- TTN | c.69970C>G p.Q23324E (on ENST00000591111; = p.Q15900E on NM_003319.4) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | PolyPhen benign (0); catalogued as COSV60042954; called by muse, mutect2, varscan2
- TTN | c.16600G>C p.E5534Q (on ENST00000591111; = p.E4607Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/162 reads (35%) | PolyPhen benign (0.122); catalogued as COSV59926392, COSV60043167; called by muse, mutect2, varscan2
- TTN | c.13264G>C p.E4422Q (on ENST00000591111; = p.E4376Q on NM_003319.4) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | PolyPhen benign (0.391); catalogued as COSV100629561, COSV60043181, COSV60343218; called by muse, mutect2, varscan2
- TTN | c.4049G>A p.R1350H (on ENST00000591111; = p.R1304H on NM_003319.4) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | PolyPhen probably damaging (0.998); catalogued as rs539470256, COSV59861393; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.1537-1G>C p.X513_splice | Splice Site (SNP) | VAF 40/128 reads (31%) | catalogued as COSV60043261; called by muse, mutect2, varscan2
- TUBGCP2 | c.2271G>A p.M757I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs755715439, COSV53305040; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs760251146; called by mutect2, varscan2
- TWF1 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100285964; called by muse, mutect2, varscan2
- TWIST1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as CM020323, COSV54250617; called by muse, mutect2, varscan2
- TXNDC11 | c.1162G>A p.A388T (on ENST00000356957 / NM_001303447.2; = p.A361T on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV51598976; called by muse, mutect2, varscan2
- TXNDC5 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51664928; called by muse, mutect2, varscan2
- TXNRD1 | c.387G>C p.K129N (on ENST00000525566 / NM_001093771.3; = p.K31N on NM_003330.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs773469710, COSV61599082; called by muse, mutect2, varscan2
- UBA2 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55828276; called by muse, mutect2, varscan2
- UBE2T | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV66153314; called by muse, mutect2, varscan2
- UBTF | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as COSV57186040; called by muse, mutect2, varscan2
- ULK4 | c.2280G>C p.L760F | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV57198403, COSV57208002; called by muse, mutect2, varscan2
- UMODL1 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349474584, COSV61160063; called by muse, mutect2, varscan2
- UNC13B | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV65934446; called by muse, mutect2, varscan2
- UNK | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs752774700, COSV52884474; called by muse, mutect2, varscan2
- URB2 | c.3239C>A p.A1080D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as COSV50981600; called by muse, mutect2, varscan2
- USH2A | c.4132C>G p.L1378V | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); catalogued as COSV56366193; called by muse, mutect2, varscan2
- USP45 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 84/121 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57328750; called by muse, mutect2, varscan2
- UTP15 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as COSV57140851; called by muse, mutect2, varscan2
- VCPIP1 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60047159; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 54/169 reads (32%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13A | c.3274G>C p.E1092Q | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.906); catalogued as COSV62429395, COSV62434500; called by muse, mutect2, varscan2
- VPS54 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV55440547; called by muse, mutect2, varscan2
- WDFY3 | c.1672C>G p.Q558E | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs374950199; called by muse, mutect2, varscan2
- WDR41 | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs370753681; called by muse, mutect2, varscan2
- WDR64 | c.3136_3138del p.K1046del | In Frame Del (DEL) | VAF 31/144 reads (22%) | catalogued as rs757773237; called by pindel, varscan2
- WNT4 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV99268599; called by muse, mutect2, varscan2
- WTAP | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs375840138; called by muse, mutect2, varscan2
- WWC1 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs760218601, COSV54647215; called by muse, mutect2, varscan2
- WWP2 | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV63124834; called by muse, mutect2, varscan2
- XPO4 | c.1173+1G>T p.X391_splice | Splice Site (SNP) | VAF 50/108 reads (46%) | catalogued as COSV55007196; called by muse, mutect2, varscan2
- YPEL5 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54395287; called by muse, mutect2, varscan2
- YTHDC2 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.614); catalogued as rs979468902, COSV50739416; called by muse, mutect2, varscan2
- ZAN | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1286980524, COSV61806193, COSV61808778; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 56/147 reads (38%) | catalogued as COSV59691020; called by mutect2, pindel, varscan2
- ZC3HC1 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV61298199; called by muse, varscan2
- ZCWPW1 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs763310132, COSV52200269; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1375A>G p.S459G | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV60156824; called by muse, mutect2, varscan2
- ZNF106 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV55515512, COSV99782238; called by muse, mutect2
- ZNF12 | c.1848G>C p.Q616H (on ENST00000405858 / NM_016265.4; = p.Q578H on NM_006956.3) | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.997); catalogued as COSV61244270; called by muse, mutect2, varscan2
- ZNF135 | c.1195C>T p.Q399* (on ENST00000313434 / NM_001289401.2; = p.Q411* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 68/163 reads (42%) | catalogued as COSV57881948; called by muse, mutect2, varscan2
- ZNF165 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV66102299, COSV66102458; called by muse, mutect2, varscan2
- ZNF212 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as rs886344237, COSV60025064; called by muse, mutect2, varscan2
- ZNF275 | c.362G>C p.R121T | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV64704425; called by muse, mutect2, varscan2
- ZNF286A | c.499G>T p.G167* | Nonsense Mutation (SNP) | VAF 8/171 reads (5%) | catalogued as COSV67845309; called by muse, mutect2
- ZNF318 | c.5287G>C p.E1763Q | Missense Mutation (SNP) | VAF 114/162 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV58932417; called by muse, mutect2, varscan2
- ZNF382 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53088213; called by muse, mutect2, varscan2
- ZNF445 | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.359); catalogued as COSV68538835; called by muse, mutect2, varscan2
- ZNF592 | c.2483A>G p.K828R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55436707; called by muse, mutect2, varscan2
- ZNF648 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.122); catalogued as rs778078667, COSV60570854; called by muse, mutect2, varscan2
- ZNF765 | c.1274C>G p.T425S | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV67182520; called by muse, mutect2, varscan2
- ZNF829 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV66986292; called by muse, mutect2, varscan2
- ZNF875 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV60991184; called by muse, mutect2, varscan2
- ZNF98 | c.306T>A p.N102K | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1568289712, COSV63335140, COSV63335366; called by muse, mutect2, varscan2
- ZNFX1 | c.617A>C p.H206P | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV65575263; called by muse, mutect2, varscan2
- ZRANB3 | c.3234G>T p.K1078N | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV51501442; called by muse, mutect2, varscan2
- ZSCAN5A | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV54226481; called by muse, mutect2, varscan2
- ZZEF1 | c.8689C>A p.R2897S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV101067546; called by muse, mutect2, varscan2
- ACTR10 | c.786C>T p.I262= | Splice Region (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- ACY3 | c.544del p.Q182Sfs*14 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel, varscan2
- ALCAM | c.458del p.K153Sfs*34 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- ARID4A | c.1920dup p.Q641Tfs*6 | Frame Shift Ins (INS) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
- ASB4 | c.634del p.L212Wfs*59 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- BAZ2B | c.6479del p.K2160Sfs*8 | Frame Shift Del (DEL) | VAF 41/142 reads (29%) | called by mutect2, pindel, varscan2
- BRSK2 | c.333del p.R112Gfs*2 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- CELSR3 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CNTNAP3 | c.1597del p.A533Rfs*10 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- CPSF2 | c.1376dup p.S460Vfs*13 | Frame Shift Ins (INS) | VAF 7/77 reads (9%) | called by pindel, varscan2
- CTIF | c.245del p.P82Hfs*77 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | called by mutect2, pindel, varscan2
- CTSS | c.439del p.A147Pfs*6 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | called by mutect2, pindel, varscan2
- CUX1 | c.619del p.T207Lfs*8 (on ENST00000292535 / NM_181552.4; = p.T218Lfs*8 on NM_001913.5) | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- EPHA4 | c.191del p.N64Ifs*12 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- FOXN1 | c.1465del p.Q489Rfs*61 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- GPR179 | c.2642C>T p.A881V (on ENST00000621958; = p.A880V on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.065); called by muse, mutect2
- KIR3DL2 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.994); called by muse, mutect2
- KMT2C | c.10108_10117del p.V3370Qfs*11 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- LRP1 | c.9884dup p.V3296Gfs*42 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- MED13L | c.754_756del p.E252del | In Frame Del (DEL) | VAF 54/190 reads (28%) | called by pindel, varscan2
- NBPF11 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NF1 | c.123del p.E41Dfs*3 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.168del p.R57Gfs*44 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.603G>C p.R201S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.072); called by mutect2, varscan2
- SCN3A | c.3439_3441del p.V1147del | In Frame Del (DEL) | VAF 44/141 reads (31%) | called by pindel, varscan2
- SFMBT1 | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- TLR4 | c.2094dup p.G699Rfs*27 (on ENST00000355622 / NM_138554.5; = p.G659Rfs*27 on NM_003266.4) | Frame Shift Ins (INS) | VAF 16/102 reads (16%) | called by pindel, varscan2
- TRAV20 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- TRAV4 | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRAV8-4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- TRBV20-1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSPAN5 | c.425dup p.N142Kfs*19 | Frame Shift Ins (INS) | VAF 36/146 reads (25%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.3215del p.P1072Qfs*11 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- WDFY3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZDHHC7 | c.837del p.S280Hfs*5 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- ZFR2 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMYM1 | c.1516del p.T506Pfs*15 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- ZNF208 | c.343del p.I115Lfs*23 | Frame Shift Del (DEL) | VAF 60/237 reads (25%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2048G>A p.R683K | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF804B | c.321dup p.Q108Tfs*6 | Frame Shift Ins (INS) | VAF 33/121 reads (27%) | called by mutect2, pindel, varscan2
- ABCA13 | c.4579C>T p.L1527= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV70028295; called by muse, mutect2, varscan2
- ACSL4 | c.387T>C p.L129= (on ENST00000340800 / NM_022977.2; = p.L88= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV61614293; called by muse, mutect2, varscan2
- ACTR8 | c.1842C>T p.R614= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV51636336; called by muse, mutect2, varscan2
- ADAM19 | c.1626G>A p.E542= | Silent (SNP) | VAF 52/160 reads (33%) | catalogued as COSV57429678; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1272G>A p.G424= | Silent (SNP) | VAF 44/76 reads (58%) | catalogued as COSV56475167; called by muse, mutect2, varscan2
- ADCY10 | c.216G>A p.V72= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV63240693; called by muse, mutect2, varscan2
- ADCY4 | c.2739C>A p.L913= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV60254103; called by muse, mutect2, varscan2
- ADGRG1 | c.840G>A p.R280= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV65635609; called by muse, mutect2, varscan2
- ADH5 | c.156G>C p.L52= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV56448122; called by muse, mutect2, varscan2
- AJUBA | c.1395C>A p.A465= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV52985482, COSV99400827; called by muse, mutect2
- ALDH1L1 | c.546G>A p.L182= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV56413832; called by muse, mutect2, varscan2
- AP2M1 | c.603G>T p.V201= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as COSV53047985; called by muse, mutect2, varscan2
- ARHGAP21 | c.5262C>T p.S1754= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs749514952, COSV57605613; called by muse, mutect2, varscan2
- ARHGAP36 | c.1515C>T p.S505= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs375497123, COSV52269551; called by muse, mutect2, varscan2
- ARHGEF1 | c.2286G>A p.L762= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV61527666; called by muse, mutect2, varscan2
- ASXL1 | c.4008G>A p.G1336= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV60107692; called by muse, mutect2, varscan2
- ATP2C2 | c.1269C>A p.V423= | Silent (SNP) | VAF 53/107 reads (50%) | catalogued as COSV52295809; called by muse, mutect2, varscan2
- BCORL1 | c.4287C>T p.T1429= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs149745711, COSV99498618; called by muse, mutect2, varscan2
- BMP10 | c.1257C>T p.S419= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs2231348, COSV54895490; called by muse, mutect2, varscan2
- BRD3 | c.1653G>A p.K551= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV57703598; called by muse, mutect2, varscan2
- BSN | c.5130C>T p.A1710= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs781023675, COSV56517519; called by muse, mutect2, varscan2
- CACNA1S | c.3507C>T p.L1169= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as COSV62939282; called by muse, mutect2, varscan2
- CALR3 | c.336C>G p.V112= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as rs185241971, COSV54169726; called by muse, mutect2, varscan2
- CAPN1 | c.1407G>A p.A469= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs745365536, COSV54198520; called by muse, mutect2, varscan2
- CAPN10 | c.561G>A p.L187= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV54376427; called by muse, mutect2, varscan2
- CAPZA2 | c.729C>T p.I243= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV63266541; called by muse, mutect2, varscan2
- CASP1 | c.105G>A p.L35= | Silent (SNP) | VAF 156/285 reads (55%) | catalogued as COSV62056488; called by muse, mutect2, varscan2
- CCDC102B | c.906G>A p.L302= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV60149546; called by muse, mutect2, varscan2
- CCDC92 | c.963G>C p.V321= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV53019745; called by muse, mutect2, varscan2
- CCT6B | c.1278G>A p.K426= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as rs114022500, COSV58489044; called by muse, mutect2, varscan2
- CCZ1B | c.678C>A p.L226= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV57437197; called by muse, mutect2, varscan2
- CDC27 | c.1884C>T p.I628= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV50382612, COSV50657329; called by muse, mutect2, varscan2
- CDH26 | c.567A>G p.A189= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV54846674; called by muse, mutect2, varscan2
- CDK5RAP2 | c.594G>A p.K198= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as rs374654660, COSV62574156; called by muse, mutect2, varscan2
- CELF1 | c.768G>A p.L256= (on ENST00000358597 / NM_001376422.1; = p.L252= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV60111787; called by muse, mutect2, varscan2
- CEP250 | c.4989G>A p.Q1663= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV61169941; called by muse, mutect2, varscan2
- CHKA | c.1113C>G p.T371= | Silent (SNP) | VAF 62/107 reads (58%) | catalogued as COSV55839801; called by muse, mutect2, varscan2
- CHST15 | c.852C>T p.I284= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV60561993; called by muse, mutect2, varscan2
- CILK1 | c.588C>G p.L196= | Silent (SNP) | VAF 64/87 reads (74%) | catalogued as COSV63154143; called by muse, mutect2, varscan2
- CLIP1 | c.3618C>G p.L1206= (on ENST00000620786 / NM_001247997.1; = p.L1195= on NM_002956.2) | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as COSV56801534; called by muse, mutect2, varscan2
- CLIP3 | c.861C>G p.L287= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV62112462; called by muse, mutect2, varscan2
- CNOT3 | c.360G>A p.E120= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV55362940; called by muse, mutect2, varscan2
- COL20A1 | c.96G>A p.L32= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs946011430, COSV58916846; called by muse, mutect2, varscan2
- CPSF1 | c.747G>A p.Q249= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV62940130; called by muse, mutect2, varscan2
- CYB5D2 | c.273C>T p.F91= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs956047318, COSV56800845; called by muse, mutect2, varscan2
- CYFIP1 | c.168C>T p.I56= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs745649616; called by muse, mutect2, varscan2
- DDX23 | c.1002G>A p.E334= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV57283617; called by muse, mutect2, varscan2
- DHRSX | c.207T>C p.H69= | Silent (SNP) | VAF 57/148 reads (39%) | catalogued as rs201283644, COSV58133394; called by muse, varscan2
- DHTKD1 | c.366C>G p.L122= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV53803432; called by muse, mutect2, varscan2
- DHX57 | c.1612C>T p.L538= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV54885127; called by muse, mutect2, varscan2
- DLGAP2 | c.813C>T p.H271= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs770219072, COSV70093878, COSV70104137; called by muse, mutect2, varscan2
- DMXL1 | c.2394C>G p.V798= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as COSV60710927; called by muse, mutect2, varscan2
- DNAH10 | c.10260C>T p.L3420= (on ENST00000409039; = p.L3359= on NM_207437.3) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV68993350; called by muse, mutect2, varscan2
- DNAJC10 | c.2112G>A p.Q704= | Silent (SNP) | VAF 66/180 reads (37%) | catalogued as COSV51138020; called by muse, mutect2, varscan2
- DNASE1L3 | c.648G>A p.L216= | Silent (SNP) | VAF 56/92 reads (61%) | catalogued as rs1165284259, COSV59155816; called by muse, mutect2, varscan2
- DNMT3A | c.138G>A p.R46= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV53051584; called by muse, mutect2, varscan2
- ECHS1 | c.714G>A p.A238= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs1324198051, COSV100881879; called by muse, mutect2
- ENAH | c.654G>A p.R218= | Silent (SNP) | VAF 98/382 reads (26%) | catalogued as COSV52867761; called by muse, varscan2
- ERBB4 | c.951A>G p.E317= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV53530291; called by muse, mutect2, varscan2
- ERBIN | c.825G>A p.L275= | Silent (SNP) | VAF 69/215 reads (32%) | catalogued as COSV52315867; called by muse, mutect2, varscan2
- ESR1 | c.822G>A p.G274= | Silent (SNP) | VAF 35/47 reads (74%) | catalogued as rs1386167068, COSV52790215; called by muse, mutect2, varscan2
- FCRL6 | c.480C>T p.G160= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV58941077; called by muse, mutect2, varscan2
- FKBP8 | c.147G>C p.L49= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV55892238; called by muse, varscan2
- FLNC | c.2652C>T p.V884= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs369714355; called by muse, mutect2, varscan2
- FOXP3 | c.1245G>A p.K415= | Silent (SNP) | VAF 37/62 reads (60%) | catalogued as COSV66051327; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.393G>A p.K131= | Silent (SNP) | VAF 50/76 reads (66%) | catalogued as COSV58552250; called by muse, mutect2, varscan2
- GABPB2 | c.627C>T p.D209= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100927191; called by muse, mutect2
- GAS6 | c.564C>G p.L188= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV59849791; called by muse, mutect2, varscan2
- GCN1 | c.2919G>A p.L973= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100324712; called by muse, varscan2
- GDNF | c.480G>A p.L160= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100427352; called by muse, mutect2, varscan2
- GMPPB | c.927C>T p.G309= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV57538500; called by muse, mutect2, varscan2
- GPR173 | c.375C>T p.I125= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs782282781, COSV60234740; called by muse, mutect2, varscan2
- GPR180 | c.597C>T p.G199= | Silent (SNP) | VAF 71/141 reads (50%) | catalogued as rs775167832, COSV65385562; called by muse, mutect2, varscan2
- GPR62 | c.69C>T p.V23= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV59054542; called by muse, mutect2, varscan2
- GPR89B | c.12G>C p.L4= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs7552095; called by mutect2, varscan2
- GRTP1 | c.630G>A p.A210= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs762654135, COSV58149993; called by muse, mutect2, varscan2
- HIPK2 | c.2580C>T p.G860= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs753069391, COSV61226745; called by muse, mutect2, varscan2
- HLA-A | c.675G>T p.L225= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV100954382, COSV65140303, COSV65141497; called by muse, varscan2
- HLA-E | c.12A>G p.G4= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100931881; called by muse, mutect2
- HOXA6 | c.465G>A p.G155= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV99762107; called by muse, mutect2
- HOXA9 | c.792C>T p.I264= | Silent (SNP) | VAF 82/242 reads (34%) | catalogued as rs377402962, COSV100604321, COSV58656083; called by muse, mutect2, varscan2
- HPCAL4 | c.282C>T p.R94= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV65716245; called by muse, mutect2, varscan2
- HYDIN | c.12507C>T p.C4169= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs1208504575, COSV66638842; called by muse, mutect2, varscan2
- IARS1 | c.1752C>T p.F584= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV65115127; called by muse, mutect2, varscan2
- IARS2 | c.2664A>G p.S888= | Silent (SNP) | VAF 72/244 reads (30%) | catalogued as COSV56959649; called by muse, mutect2, varscan2
- IGKV6-21 | c.69G>C p.L23= | Silent (SNP) | VAF 26/122 reads (21%) | called by muse, mutect2, varscan2
- IQSEC2 | c.2646C>T p.F882= (on ENST00000642864 / NM_001111125.3; = p.F677= on NM_015075.2) | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as COSV64725301; called by muse, mutect2, varscan2
- ITPR2 | c.4023C>T p.D1341= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs771963402, COSV67266243, COSV67269030; called by muse, mutect2, varscan2
- KCTD19 | c.2010C>A p.L670= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV58572800; called by muse, varscan2
- KIAA1109 | c.10779G>A p.R3593= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as COSV52672061; called by muse, mutect2, varscan2
- KIF19 | c.1419C>G p.L473= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV63429412; called by muse, mutect2, varscan2
- L3MBTL1 | c.2019G>A p.R673= (on ENST00000418998 / NM_001377303.1; = p.R583= on NM_015478.7) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV64228428; called by muse, mutect2, varscan2
- LCT | c.516C>T p.F172= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV99918778; called by muse, mutect2, varscan2
- LRRC8A | c.208C>A p.R70= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV52185623; called by muse, mutect2, varscan2
- LRRK1 | c.1572C>T p.F524= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs375733293, COSV99437961, COSV99439711; called by muse, mutect2, varscan2
- LSG1 | c.666G>C p.R222= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54570030; called by muse, mutect2, varscan2
- MAP4K2 | c.750C>G p.L250= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV53643088; called by muse, mutect2, varscan2
- MAST4 | c.4587C>T p.R1529= (on ENST00000403625 / NM_001164664.2; = p.R1340= on NM_015183.3) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs753914825, COSV55121734; called by muse, mutect2, varscan2
- MAZ | c.1131G>A p.T377= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs769154931, COSV50714952; called by muse, mutect2, varscan2
- MDH1 | c.111T>C p.I37= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV51863423, COSV99251248; called by mutect2, varscan2
- MGA | c.1812G>A p.Q604= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV54953533; called by muse, mutect2, varscan2
- MGAM | c.3363C>T p.R1121= | Silent (SNP) | VAF 93/233 reads (40%) | catalogued as COSV72074593; called by muse, mutect2, varscan2
- MKKS | c.729C>T p.L243= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as COSV61398635; called by muse, mutect2, varscan2
- MUC16 | c.34692G>A p.L11564= | Silent (SNP) | VAF 101/280 reads (36%) | catalogued as rs559195894, COSV67464280; called by muse, mutect2, varscan2
- MUSK | c.249C>G p.L83= | Silent (SNP) | VAF 63/178 reads (35%) | catalogued as COSV51885476; called by muse, mutect2, varscan2
- MYBPC2 | c.1569C>T p.L523= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs747857453, COSV63095434; called by muse, mutect2, varscan2
- NCSTN | c.1521C>T p.F507= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV99666834; called by muse, mutect2, varscan2
- NEDD4 | c.21G>A p.L7= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs761082736, COSV59061557; called by muse, mutect2, varscan2
- NLRP9 | c.2676G>A p.L892= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs746033911, COSV60462837; called by muse, mutect2, varscan2
- NTRK2 | c.1038C>T p.L346= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV52863346; called by muse, mutect2, varscan2
- NUTM2F | c.48G>A p.V16= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV53557103; called by muse, mutect2, varscan2
- OR10K1 | c.339C>T p.F113= | Silent (SNP) | VAF 73/206 reads (35%) | catalogued as rs1273485650, COSV56871794; called by muse, mutect2, varscan2
- PALB2 | c.2922G>A p.K974= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as COSV55165022; called by muse, mutect2, varscan2
- PCDHGA4 | c.2319C>T p.G773= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs779091289, COSV53943880; called by muse, mutect2, varscan2
- PCSK1 | c.147C>T p.I49= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV60735075; called by muse, mutect2, varscan2
- PEX5 | c.75C>A p.T25= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV56954753; called by muse, mutect2, varscan2
- PHF2 | c.3258G>A p.L1086= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV63680824; called by muse, mutect2, varscan2
- PHIP | c.1383C>G p.V461= | Silent (SNP) | VAF 115/165 reads (70%) | catalogued as COSV51504293; called by muse, mutect2, varscan2
- PIAS4 | c.744C>T p.L248= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV53679086; called by muse, mutect2, varscan2
- PLEKHH2 | c.117A>G p.A39= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV56753391; called by muse, mutect2, varscan2
- PODXL | c.1674C>A p.L558= (on ENST00000378555 / NM_001018111.3; = p.L526= on NM_005397.4) | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV59870162; called by muse, mutect2, varscan2
- POGLUT1 | c.819C>T p.G273= | Silent (SNP) | VAF 40/199 reads (20%) | catalogued as rs1004531113, COSV55156472; called by muse, mutect2, varscan2
- POU4F1 | c.1086C>T p.I362= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1262651287, COSV65884278; called by muse, mutect2, varscan2
- PPP4R4 | c.366C>T p.D122= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs1253179862, COSV100175598; called by muse, mutect2
- PRKD3 | c.1701T>C p.N567= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV52213295; called by muse, mutect2, varscan2
- PRSS55 | c.726C>T p.S242= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV60808261; called by muse, mutect2, varscan2
- PTCH1 | c.4294C>T p.L1432= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs763583281, COSV59473314; called by muse, mutect2, varscan2
- PTK7 | c.1722C>T p.N574= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs760857931, COSV57847284; called by muse, varscan2
- PTPRM | c.285C>T p.H95= | Silent (SNP) | VAF 54/101 reads (53%) | catalogued as COSV59857633; called by muse, mutect2, varscan2
- PTPRT | c.258G>A p.Q86= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs754128523, COSV61962223, COSV61980073; called by muse, varscan2
74 further variants in this file (0 protein-altering or splice-affecting, 61 silent, 13 other) are not listed here.
